CCDI case PBBMLN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/ae02627e-63f2-473c-951b-c3ba71cc7b27

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 4.1 years (1,494 days).

Biospecimens (3 samples)
- Sample 0DCEQT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCEQZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCER6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
